Somatic mutation profile of tumor specimen MP2PRT-PASPBR-TMP1-A (aliquot MP2PRT-PASPBR-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASPBR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,719 days).
Specimen MP2PRT-PASPBR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57fee71f-08b8-42d7-9647-a07fde625f6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASPBR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASPBR-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c6a1400-bb91-4878-b69f-bf2b326f276e

The open-access MAF lists 44 somatic variants for this specimen: 30 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 11, Nonsense Mutation 2, Frame Shift Ins 1, 5'Flank 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- UGT1A1 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 118/466 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72551343, CM931125; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACACA | c.6749C>T p.T2250I | Missense Mutation (SNP) | VAF 18/539 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs1464505136; called by muse, mutect2
- ARIH1 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65913097; called by muse, mutect2
- ATP13A3 | c.2455G>C p.E819Q | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.157); catalogued as rs1298526392, COSV99756944; called by muse, mutect2, varscan2
- C1QL4 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 82/504 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1565675613, COSV57743163; called by muse, mutect2, varscan2
- CELSR2 | c.6643G>A p.V2215M | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs960244196; called by muse, mutect2, varscan2
- CTCF | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 85/361 reads (24%) | catalogued as COSV50461476; called by muse, mutect2, varscan2
- DDX51 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs181712364, COSV57958437; called by muse, mutect2, varscan2
- DLG2 | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 33/319 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759888051; called by muse, mutect2, varscan2
- EPHB4 | c.1039dup p.L347Pfs*34 | Frame Shift Ins (INS) | VAF 96/438 reads (22%) | catalogued as rs767827881; called by mutect2, pindel, varscan2
- GRIN2D | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 90/401 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs1335359278; called by muse, mutect2, varscan2
- INSR | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57173643; called by muse, mutect2, varscan2
- MFAP3L | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 83/336 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779772218, COSV64371771; called by muse, mutect2, varscan2
- MS4A15 | c.286C>T p.R96C (on ENST00000405633 / NM_001098835.2; = p.R3C on NM_152717.3) | Missense Mutation (SNP) | VAF 65/606 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1340358912; called by muse, mutect2, varscan2
- NR2E3 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 44/442 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs544807110, CM134234, COSV58908484; called by muse, mutect2
- RNF152 | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1342172334, COSV57185409; called by muse, mutect2, varscan2
- ROR1 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 60/556 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs867500485, COSV64290455; called by muse, mutect2, varscan2
- ROR2 | c.1027C>A p.Q343K | Missense Mutation (SNP) | VAF 121/466 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); catalogued as COSV65219112; called by muse, mutect2, varscan2
- RXFP3 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 138/585 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1225974660, COSV57503985; called by muse, mutect2, varscan2
- TTN | c.85603G>C p.E28535Q (on ENST00000591111; = p.E21111Q on NM_003319.4) | Missense Mutation (SNP) | VAF 34/408 reads (8%) | PolyPhen probably damaging (0.964); catalogued as COSV59910602, COSV59926719; called by muse, mutect2
- ZFP41 | c.77G>C p.R26T | Missense Mutation (SNP) | VAF 78/292 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV58085920, COSV58087798; called by muse, mutect2, varscan2
- ANKRD7 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2
- APEX2 | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 30/806 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- CCDC7 | c.2534A>G p.E845G | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CNTN3 | c.1568T>A p.V523E | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DYNC2H1 | c.8315T>A p.I2772N | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- FDXACB1 | c.1328C>G p.S443* | Nonsense Mutation (SNP) | VAF 73/367 reads (20%) | called by muse, mutect2, varscan2
- MYO1D | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TMCO3 | c.1589G>C p.G530A | Missense Mutation (SNP) | VAF 87/484 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZNF85 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 17/492 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2
- CNTN6 | c.1230C>T p.F410= | Silent (SNP) | VAF 26/232 reads (11%) | called by muse, mutect2, varscan2
- CPNE4 | c.372G>A p.Q124= | Silent (SNP) | VAF 34/239 reads (14%) | called by muse, mutect2, varscan2
- ELOA2 | c.52C>T p.L18= | Silent (SNP) | VAF 114/467 reads (24%) | catalogued as COSV55303852; called by muse, mutect2, varscan2
- FDXACB1 | c.972C>G p.L324= | Silent (SNP) | VAF 78/369 reads (21%) | called by muse, mutect2, varscan2
- KRT6B | c.510C>G p.L170= | Silent (SNP) | VAF 63/545 reads (12%) | called by muse, mutect2, varscan2
- NOTCH1 | c.3060C>T p.H1020= | Silent (SNP) | VAF 53/517 reads (10%) | catalogued as rs1441635299; called by muse, mutect2, varscan2
- NUP188 | c.4665C>G p.L1555= | Silent (SNP) | VAF 97/452 reads (21%) | called by muse, mutect2, varscan2
- PCNT | c.4860A>C p.L1620= | Silent (SNP) | VAF 42/843 reads (5%) | called by muse, mutect2
- PLAT | c.435C>T p.G145= | Silent (SNP) | VAF 135/528 reads (26%) | catalogued as rs141317668, COSV99535149; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR64 | c.2085T>G p.P695= | Silent (SNP) | VAF 42/334 reads (13%) | called by muse, mutect2, varscan2
- ZPLD1 | c.1104C>T p.N368= (on ENST00000466937 / NM_001329788.1; = p.N384= on NM_175056.2) | Silent (SNP) | VAF 80/316 reads (25%) | catalogued as rs887317312; called by muse, mutect2, varscan2
- CCDC144NL | n.619C>T | RNA (SNP) | VAF 143/533 reads (27%) | called by muse, mutect2, varscan2
- DOCK8 | chr9:214718 C>G | 5'Flank (SNP) | VAF 95/803 reads (12%) | called by muse, mutect2, varscan2
- NFIB | c.*12T>C | 3'UTR (SNP) | VAF 53/182 reads (29%) | called by muse, mutect2, varscan2
